Somatic mutation profile of tumor specimen TCGA-G8-6907-01A (aliquot TCGA-G8-6907-01A-11D-2210-10) from TCGA case TCGA-G8-6907, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 57.6 years (21,021 days).
Specimen TCGA-G8-6907-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 126922df-4219-43ec-9a04-87f8dc6f6336.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G8-6907-14A (Bone Marrow Normal), aliquot TCGA-G8-6907-14A-01D-2210-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6feccd3a-fab3-41eb-9e37-7532dc27621a

The open-access MAF lists 76 somatic variants for this specimen: 62 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 13, Nonsense Mutation 8, Splice Site 4, Frame Shift Del 4, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EZH2 | c.1922A>C p.Y641S (on ENST00000460911 / NM_001203247.2; = p.Y646S on NM_004456.5) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as rs267601394, COSV57445929, COSV57446008, COSV57446054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FAS | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 54/64 reads (84%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as rs121913078, CM971493, COSV58238587; ClinVar: pathogenic; called by muse, mutect2, varscan2
- B2M | c.26T>A p.V9E | Missense Mutation (SNP) | VAF 49/53 reads (92%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV62563191, COSV62566352; called by muse, mutect2, varscan2
- BCL6 | c.2016G>C p.Q672H | Missense Mutation (SNP) | VAF 70/139 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51652641; called by muse, mutect2, varscan2
- CDHR3 | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 71/169 reads (42%) | catalogued as rs1041484811; called by muse, mutect2, varscan2
- CNTNAP5 | c.3557C>T p.A1186V | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.34); catalogued as rs756574947; called by muse, mutect2, varscan2
- EGFR | c.1189A>C p.T397P | Missense Mutation (SNP) | VAF 76/170 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51796177; called by muse, mutect2, varscan2
- IGLC3 | c.169A>G p.T57A | Missense Mutation (SNP) | VAF 231/466 reads (50%) | PolyPhen benign (0); catalogued as rs752091340; called by muse, mutect2, varscan2
- IGLV1-47 | c.162C>G p.Y54* | Nonsense Mutation (SNP) | VAF 124/274 reads (45%) | catalogued as rs572649201; called by muse, varscan2
- IGLV5-37 | c.152G>A p.S51N | Missense Mutation (SNP) | VAF 40/42 reads (95%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs758030557; called by muse, varscan2
- LAMA5 | c.5792G>A p.R1931Q | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.139); catalogued as rs372008452; called by muse, mutect2, varscan2
- MEF2B | c.248A>T p.D83V | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV50761376, COSV50764249; called by muse, mutect2, varscan2
- MTUS1 | c.1393C>T p.P465S | Missense Mutation (SNP) | VAF 46/231 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as rs769142666; called by muse, mutect2, varscan2
- NAA15 | c.1186T>G p.Y396D | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV56719348; called by muse, mutect2, varscan2
- POTEE | c.1948A>G p.T650A | Missense Mutation (SNP) | VAF 149/366 reads (41%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs754771655; called by muse, mutect2, varscan2
- PTEN | c.226T>G p.Y76D | Missense Mutation (SNP) | VAF 55/67 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64292967; called by muse, mutect2, varscan2
- RB1 | c.341C>A p.S114* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV57311725, COSV57328604; called by mutect2, varscan2
- RB1 | c.2390T>A p.L797* | Nonsense Mutation (SNP) | VAF 8/78 reads (10%) | catalogued as CM023820, COSV57317102, COSV57328972; called by muse, mutect2
- SLC25A52 | c.604G>A p.G202S (on ENST00000672005; = p.G192S on NM_001034172.4) | Missense Mutation (SNP) | VAF 18/261 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.033); catalogued as COSV52503641; called by muse, mutect2
- STAG2 | c.940A>G p.I314V | Missense Mutation (SNP) | VAF 73/218 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750012413; called by muse, mutect2, varscan2
- TAB1 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.139); catalogued as rs751636187; called by muse, mutect2, varscan2
- TLR2 | c.983T>G p.L328R | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV52605179; called by muse, mutect2, varscan2
- TMSB4X | c.66_67del p.E22Dfs*14 | Frame Shift Del (DEL) | VAF 121/206 reads (59%) | catalogued as rs1311307403; called by pindel, varscan2
- ZFHX4 | c.4198A>C p.N1400H | Missense Mutation (SNP) | VAF 101/222 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV51443977; called by muse, mutect2, varscan2
- ALMS1 | c.7530del p.R2511Efs*7 | Frame Shift Del (DEL) | VAF 41/134 reads (31%) | called by mutect2, pindel, varscan2
- ARHGAP9 | c.1246C>T p.Q416* | Nonsense Mutation (SNP) | VAF 40/100 reads (40%) | called by mutect2, varscan2
- BLM | c.3326T>A p.F1109Y | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.83); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- BTK | c.1109T>C p.I370T | Missense Mutation (SNP) | VAF 130/139 reads (94%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- DNAAF4 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAJC9 | c.354_360del p.T119Kfs*39 | Frame Shift Del (DEL) | VAF 40/124 reads (32%) | called by mutect2, pindel, varscan2
- DSCC1 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- DYSF | c.4494_4509+3del p.X1498_splice | Splice Site (DEL) | VAF 95/231 reads (41%) | called by mutect2, pindel, varscan2
- EXOC4 | c.2613T>G p.C871W | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FBF1 | c.314A>G p.D105G (on ENST00000586717; = p.D119G on NM_001319193.1) | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FLNA | c.1063A>C p.K355Q | Missense Mutation (SNP) | VAF 119/216 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- GNA13 | c.1015C>T p.Q339* | Nonsense Mutation (SNP) | VAF 122/141 reads (87%) | called by muse, mutect2, varscan2
- GRIN2D | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- HELB | c.1390A>G p.M464V | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- IDH3B | c.403A>G p.K135E | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- IGLV1-47 | c.342C>G p.S114R | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.076); called by muse, varscan2
- IGSF22 | c.1924T>C p.Y642H | Missense Mutation (SNP) | VAF 15/243 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); called by muse, mutect2
- LALBA | c.369-1G>T p.X123_splice | Splice Site (SNP) | VAF 50/103 reads (49%) | called by muse, mutect2, varscan2
- LMTK3 | c.117C>A p.Y39* | Nonsense Mutation (SNP) | VAF 62/141 reads (44%) | called by muse, mutect2, varscan2
- MAMLD1 | c.1190C>A p.A397D | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- MAN1A2 | c.555_558+7del p.X185_splice | Splice Site (DEL) | VAF 34/101 reads (34%) | called by mutect2, pindel, varscan2
- MYO6 | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- PASK | c.246T>G p.I82M | Missense Mutation (SNP) | VAF 202/455 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PCDH7 | c.2819dup p.N940Kfs*5 | Frame Shift Ins (INS) | VAF 45/98 reads (46%) | called by mutect2, pindel, varscan2
- PHF12 | c.131A>T p.E44V | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PLCG2 | c.3712A>T p.N1238Y | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- PRSS53 | c.632G>A p.G211D | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYK | c.1608G>T p.W536C (on ENST00000620660 / NM_001005861.2; = p.W533C on NM_002958.4) | Missense Mutation (SNP) | VAF 76/140 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCAP | c.3204T>A p.C1068* | Nonsense Mutation (SNP) | VAF 76/164 reads (46%) | called by muse, mutect2, varscan2
- SRP54 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- STK10 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); called by muse, mutect2
- STK10 | c.922G>T p.A308S | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- TAB1 | c.497C>A p.A166D | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- TNFAIP8L2 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- TTC38 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- VPS50 | c.702+2T>G p.X234_splice | Splice Site (SNP) | VAF 40/103 reads (39%) | called by muse, mutect2, varscan2
- ZFPM2 | c.1719C>A p.S573R | Missense Mutation (SNP) | VAF 86/170 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF560 | c.1110_1111del p.I371Wfs*6 | Frame Shift Del (DEL) | VAF 88/244 reads (36%) | called by pindel, varscan2
- AUTS2 | c.1851C>T p.V617= | Silent (SNP) | VAF 44/92 reads (48%) | catalogued as rs139965676; called by muse, mutect2, varscan2
- EPS15 | c.2322G>A p.K774= | Silent (SNP) | VAF 98/218 reads (45%) | catalogued as COSV65543537; called by muse, mutect2, varscan2
- FAM47B | c.531C>T p.T177= | Silent (SNP) | VAF 98/114 reads (86%) | catalogued as rs149160457, COSV100264047; called by muse, mutect2, varscan2
- GRIK3 | c.234C>A p.T78= | Silent (SNP) | VAF 95/204 reads (47%) | catalogued as COSV100901396, COSV66137921; called by muse, varscan2
- GRIN2A | c.2562C>T p.S854= | Silent (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- IGLV1-47 | c.343C>T p.L115= | Silent (SNP) | VAF 50/102 reads (49%) | catalogued as rs1250115232; called by muse, varscan2
- MAGEE1 | c.1107G>A p.P369= | Silent (SNP) | VAF 59/63 reads (94%) | catalogued as COSV63912055; called by muse, mutect2, varscan2
- NHSL2 | c.1059G>A p.S353= (on ENST00000510661; = p.S719= on NM_001013627.2) | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as rs921664221; called by muse, mutect2
- PTPRO | c.2217G>C p.V739= | Silent (SNP) | VAF 67/147 reads (46%) | called by muse, mutect2, varscan2
- SENP3 | c.1653C>T p.F551= | Silent (SNP) | VAF 55/110 reads (50%) | called by muse, mutect2, varscan2
- SP4 | c.151C>T p.L51= | Silent (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- SV2C | c.420G>A p.L140= | Silent (SNP) | VAF 12/134 reads (9%) | called by muse, mutect2
- TMTC4 | c.1884C>T p.L628= (on ENST00000376234 / NM_001350577.2; = p.L647= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 127/280 reads (45%) | catalogued as COSV100168424; called by muse, mutect2, varscan2
- PHPT1 | c.*98G>A | 3'UTR (SNP) | VAF 11/19 reads (58%) | catalogued as rs531142767, COSV99916030; called by muse, mutect2, varscan2
